Somatic mutation profile of tumor specimen TCGA-E3-A3E0-01A (aliquot TCGA-E3-A3E0-01A-11D-A20C-08) from TCGA case TCGA-E3-A3E0, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 34.6 years (12,645 days).
Specimen TCGA-E3-A3E0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a3d1b3f-4bfa-42c7-853b-b5dd31167153.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E3-A3E0-10A (Blood Derived Normal), aliquot TCGA-E3-A3E0-10A-01D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/648c5559-f7f4-4356-8783-ea800735580a

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A5 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569488426, CM129358, COSV60361481; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCL11A | c.1729G>A p.E577K (on ENST00000335712 / NM_001365609.1; = p.E611K on NM_018014.4) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.548); catalogued as COSV59634856; called by muse, mutect2, varscan2
- CPSF3 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53011135; called by muse, mutect2, varscan2
- PGM5 | c.559A>G p.K187E | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV67164729; called by muse, mutect2, varscan2
- RAPGEF6 | c.3797A>T p.H1266L | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.284); catalogued as COSV57252756; called by muse, mutect2, varscan2
- GOT1L1 | c.390C>T p.Y130= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1410070469, COSV56877164; called by muse, mutect2, varscan2
- MUC13 | c.1287C>A p.I429= | Silent (SNP) | VAF 28/160 reads (18%) | catalogued as COSV100222175, COSV60700760; called by muse, mutect2, varscan2
- NOP9 | c.1800G>T p.V600= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as COSV51867263; called by muse, mutect2, varscan2
